Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A17U, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A17U-01A (Primary Tumor).

[page 1 of 4]
1CD-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Site code: Endometrium C54.1 *lw*

Surgical Pathology

DIAGNOSIS:

A.Uterus, bilateral ovaries, and fallopian tubes, hysterectomy and bilateral salpingo-oophorectomy: FIGO grade II (of III) endometrial adenocarcinoma, endometrioid type, is identified forming a mass (6.1 x 2.1 x 1.9 cm), circumferentially involving the endometrial cavity. The tumor invades 1.8 cm into the myometrium (total wall thickness 1.8 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. The tumor involves the left and right tube. The bilateral ovaries are uninvolved. The surgical margins are negative for tumor. [AJCC pT3a N1 MX].

B.Lymph nodes, right para-aortic above IMA, excision: One of 2 lymph nodes are positive for tumor.

C.Lymph nodes, right para-aortic below IMA, excision: One of 2 lymph nodes are positive for tumor.

D.Lymph nodes, presacral, excision: Three lymph nodes are negative for tumor.

E.Lymph nodes, left para-aortic, excision: Two of 5 lymph nodes are positive for tumor.

F.Vessels, left gonadal, excision: Negative for tumor.

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes

[page 2 of 4]
identified on permanent section review will be reflected in a revised report.

DIAGNOSIS COMMENT:

An immunohistochemical stain for p53 was performed on Block A8 (right fallopian tube) and was negative in tumor cells. This finding supports the above interpretation.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, right and left fallopian tubes and ovaries" is a 150 gram uterus with attached bilateral tubes and ovaries and an unremarkable cervix. The uterine serosa has diffuse adhesions on posterior and anterior lateral surface with adipose tissue adhered to the fundus and anterolateral surface. There is a 6.1 x 2.4 x 1.9 cm mass involving the entire endometrial cavity which grossly appears to invade 1.6 cm into the 1.8 cm thick myometrium. There is a 2.0 x 1.5 x 0.6 cm right ovary with a smooth outer surface and a solid cut surface with a 7.0 x 0.6 cm right fallopian tube. There is a 2.5 x 2.0 x 1.2 cm left ovary with a smooth outer surface and a solid cut surface with a 7.5 x 0.7 left fallopian tube. Representative sections submitted.

B. Received fresh labeled "right para-aortic nodes above IMA" is a 5.1 x 1.9 x 1.2 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

[page 3 of 4]
C. Received fresh labeled "right para-aortic nodes below IMA" is

a 4.7 x 1.9 x 1.3 cm aggregate of adipose and lymphatic tissue. All

lymphatic tissue submitted.

D. Received fresh labeled "presacral lymph nodes " is a 4.0 x

2.9 x 1.0 cm aggregate of adipose and lymphatic tissue.

All

lymphatic tissue submitted.

E. Received fresh labeled "left para-aortic nodes" is a 5.8 x

3.5 x 1.4 cm aggregate of adipose and lymphatic tissue.

All

lymphatic tissue submitted.

F. Received fresh labeled "left gonadal vessels" is a 4.8 cm in

length by 0.2 cm in diameter portion of unremarkable blood vessel.

A representative section is submitted.

BLOCK SUMMARY:

Part A: Uterus, tubes, ovaries

- 1 Endometrial tumor-1
- 2 Endometrial tumor-2
- 3 Endometrial tumor-3
- 4 Endometrial tumor-4
- 5 Lower uterine segment
- 6 Cervix at 6:00
- 7 Right ovary
- 8 Rt fallopian tube
- 9 Left ovary
- 10 Lt fallopian tube
- 11 Endometrial tumor-5
- 12 Rt fallopian tube-2

Part B: Right Para-aortic Lymph Nodes above IMA

- 1 Rt above IMA lns-2(B1)
- 2 Rt above IMA ln-10f2(B2)
- 3 Rt above IMA ln-2of3(B2)
- 4 Rt above IMA ln-3of3(B2)

[page 4 of 4]
Part C: Right Para-aortic Lymph Nodes below IMA

- 1 Rt below IMA ln-1(C1)
- 2 Rt below IMA ln-1of3(C2)
- 3 Rt below IMA ln-2of3(C2)
- 4 Rt below IMA ln-3of3(C2)

Part D: Presacral lymph nodes

- 1 Presacral lns-3(D1)
- 2 Presacral lns-2-(D2)

Part E: Left Para-aortic Lymph Nodes

- 1 Lt para-aortic lns-3(E1)
- 2 Lt para-aortic ln-1of2(E2)
- 3 Lt para-aortic ln-2of2(E2)
- 4 Lt para-aortic ln-1(E3)
- 5 Lt para-aortic ln-1of4(E4)
- 6 Lt para-aortic ln-2of4(E4)
- 7 Lt para-aortic ln-3of4(E4)
- 8 Lt para-aortic ln-4of4(E4)

Part F: Left Gonadal vessels

- 1 Lt gonadal vessels

Source: NCI Genomic Data Commons file 45596209-9867-4e00-8220-1abe4380d796 (TCGA-D1-A17U.A0A4164D-FD8D-4472-BAFA-A036469E22CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).